Somatic mutation profile of tumor specimen MMRF_2111_1_BM_CD138pos (aliquot MMRF_2111_1_BM_CD138pos_T1_KHS5U_L08152) from MMRF case MMRF_2111, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.5 years (22,107 days).
Specimen MMRF_2111_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30cea86c-405f-4366-af83-fa80b38f0be3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2111_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2111_1_PB_Whole_C2_KHS5U_L08153; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bbd6a26-8868-4119-a71b-d44a92ea1016

The open-access MAF lists 108 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 29, Missense Mutation 29, Intron 18, Silent 8, 5'Flank 6, 5'UTR 5, Splice Site 3, 3'Flank 3, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1A | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99371751; called by muse, mutect2, varscan2
- CELA2A | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs184256573; called by muse, mutect2, varscan2
- DOCK5 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs756926698; called by muse, mutect2, varscan2
- FUBP1 | c.344-2A>T p.X115_splice | Splice Site (SNP) | VAF 20/53 reads (38%) | catalogued as COSV53935906; called by muse, mutect2, varscan2
- GOLGA4 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1462470619, COSV62711471; called by muse, mutect2, varscan2
- GUCY1A2 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1158659122; called by muse, mutect2, varscan2
- H2BC11 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 161/247 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV60362595; called by muse, mutect2, varscan2
- IGFN1 | c.3245C>T p.S1082L (on ENST00000295591 / NM_001367841.1; = p.S3539L on NM_001164586.2) | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV55177404; called by muse, mutect2, varscan2
- IGHJ1 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 50/53 reads (94%) | catalogued as rs781831936; called by muse, varscan2
- IGLL5 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs536568891; called by muse, mutect2, varscan2
- IGLL5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs6003368, COSV73248992, COSV73250942, COSV73250989, COSV73251049; called by muse, mutect2, varscan2
- IGLV3-1 | c.47-2A>C p.X16_splice | Splice Site (SNP) | VAF 70/129 reads (54%) | catalogued as rs181922188; called by muse, mutect2, varscan2
- ITSN1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67156895; called by muse, mutect2, varscan2
- KLHL29 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1014456936, COSV56022545; called by muse, mutect2, varscan2
- PAK1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99584005; called by muse, mutect2, varscan2
- PFAS | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs780341545, COSV58983662; called by muse, mutect2, varscan2
- PLEKHG4 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs748087287; called by muse, mutect2, varscan2
- PPP1R21 | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1389321893; called by muse, mutect2, varscan2
- RIMS2 | c.2192T>C p.L731P (on ENST00000666250 / NM_001348490.2; = p.L539P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51710324; called by muse, mutect2
- SGSM1 | c.2861C>T p.T954M (on ENST00000400359 / NM_001039948.4; = p.T893M on NM_133454.3) | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs370742946; called by muse, mutect2, varscan2
- SOSTDC1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1410527496; called by muse, mutect2
- SSTR1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs780849284; called by muse, mutect2, varscan2
- SYDE1 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.113); catalogued as rs1239698803; called by muse, mutect2, varscan2
- BIRC6 | c.6855C>A p.H2285Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.7167_7175del p.G2390_M2392del | In Frame Del (DEL) | VAF 81/296 reads (27%) | called by mutect2, pindel, varscan2
- DSC2 | c.1504A>C p.S502R | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- EP400 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FUBP1 | c.556dup p.A186Gfs*10 | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | called by pindel, varscan2
- ISM1 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MGA | c.5110G>A p.A1704T | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.113); called by muse, mutect2
- POT1 | c.1044_1068del p.C349Lfs*10 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- PTPRN | c.1315_1326del p.P439_P442del | In Frame Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.4649C>T p.P1550L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TARS3 | c.690+4A>G | Splice Region (SNP) | VAF 19/282 reads (7%) | called by muse, mutect2
- TLR7 | c.1315dup p.S439Ffs*3 | Frame Shift Ins (INS) | VAF 36/52 reads (69%) | called by mutect2, pindel, varscan2
- TRPM3 | c.4491C>A p.Y1497* (on ENST00000357533 / NM_001366142.2; = p.Y1352* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2, varscan2
- TRPM3 | c.4490A>T p.Y1497F (on ENST00000357533 / NM_001366142.2; = p.Y1352F on NM_020952.6) | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TYMP | c.766-1G>A p.X256_splice | Splice Site (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- ZBED8 | c.1460A>C p.D487A | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- BSN | c.9051C>T p.L3017= | Silent (SNP) | VAF 103/280 reads (37%) | called by muse, mutect2, varscan2
- CEP250 | c.4779T>C p.L1593= | Silent (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- CLDN10 | c.318C>T p.V106= | Silent (SNP) | VAF 115/359 reads (32%) | catalogued as rs374567220; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.4233A>G p.G1411= | Silent (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- DENND2C | c.2718G>A p.S906= (on ENST00000393274 / NM_001256404.2; = p.S849= on NM_198459.4) | Silent (SNP) | VAF 142/353 reads (40%) | catalogued as rs752083774, COSV101283971; called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, varscan2
- MROH2B | c.4275T>C p.F1425= | Silent (SNP) | VAF 83/228 reads (36%) | called by muse, mutect2, varscan2
- UNC79 | c.2133A>C p.G711= (on ENST00000393151 / NM_001346218.2; = p.G534= on NM_020818.5) | Silent (SNP) | VAF 65/133 reads (49%) | called by muse, mutect2, varscan2
- AC016596.1 | chr5:56003478 A>G | 5'Flank (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- AEN | c.540+31G>C | Intron (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- ALAD | c.*767T>G | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- ANK1 | c.5619+725G>A | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- AP001893.2 | chr11:126175989 C>T | 3'Flank (SNP) | VAF 186/433 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7186G>A | Intron (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- ARPP21 | c.-38-359A>C | Intron (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- ASB13 | c.232-46C>T | Intron (SNP) | VAF 24/119 reads (20%) | catalogued as rs778321274; called by muse, mutect2, varscan2
- BCL7A | chr12:122021355 A>G | 5'Flank (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- CDK20 | c.*258G>A | 3'UTR (SNP) | VAF 548/887 reads (62%) | catalogued as rs1427207188; called by muse, mutect2, varscan2
- CIBAR1 | c.261+921C>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- CNTN4 | c.*1262A>C | 3'UTR (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- CPTP | c.*52G>A | 3'UTR (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+212A>T | Intron (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- CSF1 | c.-151A>C | 5'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*1687C>T | 3'UTR (SNP) | VAF 10/340 reads (3%) | called by muse, mutect2
- EPHA5 | c.3008+1362T>C | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- F2RL3 | c.-47G>T | 5'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- FAAP20 | chr1:2199078 C>G | 5'Flank (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2
- FAM20C | c.864-16915G>A | Intron (SNP) | VAF 15/62 reads (24%) | catalogued as rs564315339; called by muse, mutect2, varscan2
- FBXO42 | c.*3730G>A | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- FER | c.*8768G>A | 3'UTR (SNP) | VAF 43/67 reads (64%) | called by muse, mutect2, varscan2
- FEZ1 | c.-271C>T | 5'UTR (SNP) | VAF 145/316 reads (46%) | catalogued as rs749699666; called by muse, mutect2, varscan2
- GLB1 | c.76-4418G>A | Intron (SNP) | VAF 49/105 reads (47%) | catalogued as rs778120932; called by muse, mutect2, varscan2
- GLOD4 | c.589-35C>A | Intron (SNP) | VAF 9/92 reads (10%) | catalogued as rs760928077; called by muse, mutect2, varscan2
- H1-0 | c.-409G>A | 5'UTR (SNP) | VAF 15/337 reads (4%) | called by muse, mutect2
- KALRN | c.*1201G>A | 3'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as rs1392933874; called by muse, mutect2, varscan2
- LCNL1 | c.*235C>T | 3'UTR (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- LMO3 | c.*2247A>C | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- LOX | c.*1225A>G | 3'UTR (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- MMS22L | c.*736G>T | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- MSLN | chr16:769352 A>G | 3'Flank (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- MT3 | chr16:56589157 C>T | 5'Flank (SNP) | VAF 67/160 reads (42%) | called by muse, mutect2, varscan2
- MTSS1 | c.*1028T>C | 3'UTR (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- NET1 | c.256-5175C>T | Intron (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- PAQR8 | c.*3299A>C | 3'UTR (SNP) | VAF 34/114 reads (30%) | called by muse, varscan2
- PI15 | c.*2747T>A | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- PI15 | c.*3159T>G | 3'UTR (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- POU3F2 | c.*2425C>T | 3'UTR (SNP) | VAF 8/137 reads (6%) | catalogued as COSV100099361; called by muse, mutect2
- PPFIA4 | c.2985-24G>T | Intron (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- PPHLN1 | c.*141T>A | 3'UTR (SNP) | VAF 10/169 reads (6%) | called by muse, mutect2
- PPP1R2 | c.*704A>T | 3'UTR (SNP) | VAF 130/249 reads (52%) | called by muse, mutect2, varscan2
- PPP3R2 | c.*2317A>C | 3'UTR (SNP) | VAF 65/92 reads (71%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676838 G>T | 3'Flank (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- RABEP1 | c.2271+60C>T | Intron (SNP) | VAF 86/194 reads (44%) | called by muse, mutect2, varscan2
- RBM38 | c.416+6617T>A | Intron (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- RGR | c.*1115del | 3'UTR (DEL) | VAF 17/39 reads (44%) | catalogued as rs551804100; called by mutect2, varscan2
- RGS12 | c.3234+28G>A | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs112157563; called by muse, mutect2, varscan2
- RNF34 | c.*249T>C | 3'UTR (SNP) | VAF 68/141 reads (48%) | catalogued as rs948121243; called by muse, mutect2, varscan2
- RPGRIP1L | c.*134T>C | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- RXFP3 | c.-127C>A | 5'UTR (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- SEMA3C | c.*385G>T | 3'UTR (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- SGK2 | c.*46G>A | 3'UTR (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- SH2D5 | c.*735C>T | 3'UTR (SNP) | VAF 68/150 reads (45%) | catalogued as rs552094017; called by muse, mutect2, varscan2
- SLC15A4 | c.*330C>T | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855449 C>T | 5'Flank (SNP) | VAF 67/136 reads (49%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-3864T>G | Intron (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- TAOK3 | c.988-27del | Intron (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- TXLNA | c.*165T>C | 3'UTR (SNP) | VAF 16/39 reads (41%) | catalogued as rs930848163; called by muse, mutect2, varscan2
- UBE2N | c.*676T>G | 3'UTR (SNP) | VAF 83/186 reads (45%) | called by muse, mutect2, varscan2
- XKR8 | chr1:27959969 C>T | 5'Flank (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
